Somatic mutation profile of tumor specimen 0DH5VQ from CCDI case PBBTNX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Granulosa cell tumor, juvenile; Tissue or organ of origin: Ovary; Age at diagnosis: 15.1 years (5,531 days).
Specimen 0DH5VQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90a726e8-dc57-495a-ad20-6536618d2e75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH5U5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0edf5d59-0e7b-40ac-9ec5-38fe7be1ab89

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.3065G>A p.R1022Q | Missense Mutation (SNP) | VAF 237/966 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs538019177; called by muse, varscan2
- IRX6 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 36/485 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs200849204, COSV99306618; called by muse, mutect2
- C7orf57 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 74/1085 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); called by muse, mutect2
- GATA4 | c.842T>A p.L281Q | Missense Mutation (SNP) | VAF 265/1078 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUSK | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 80/1414 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- GATA4 | c.843G>T p.L281= | Silent (SNP) | VAF 265/1083 reads (24%) | catalogued as COSV58735920; called by muse, mutect2, varscan2
- GLIS1 | c.1245G>A p.S415= | Silent (SNP) | VAF 82/833 reads (10%) | catalogued as rs765213453; called by muse, mutect2, varscan2
- DCAF8 | c.724-71G>A | Intron (SNP) | VAF 62/264 reads (23%) | catalogued as rs1008244329; called by muse, mutect2, varscan2
- PSMA4 | c.3+48del | Intron (DEL) | VAF 187/810 reads (23%) | called by mutect2, varscan2
